Somatic mutation profile of tumor specimen 0DEHOC from CCDI case PBBPWE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.1 years (4,051 days).
Specimen 0DEHOC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3b9383a-5b3c-4e73-a329-5c995d408c6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHN6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8187d2ec-e663-4d66-938d-8dd9dc366dbf

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASP2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs780908429; called by muse, mutect2, varscan2
- CDH23 | c.6061G>A p.V2021M | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs923700936, COSV56446224, COSV56469241; called by muse, mutect2
- DPRX | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as rs752355371, COSV64949213; called by muse, mutect2, varscan2
- PCDHB10 | c.2192A>C p.E731A | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV53376468; called by muse, mutect2, varscan2
- C15orf62 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF784 | c.648C>T p.R216= | Silent (SNP) | VAF 70/311 reads (23%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3238A>G | Intron (SNP) | VAF 68/462 reads (15%) | called by muse, mutect2
